Somatic mutation profile of tumor specimen TCGA-A5-A2K5-01A (aliquot TCGA-A5-A2K5-01A-11D-A17W-09) from TCGA case TCGA-A5-A2K5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.8 years (28,057 days).
Specimen TCGA-A5-A2K5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e8b28d3-f7f9-4b12-b1f8-5a5b5d0183d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A2K5-10A (Blood Derived Normal), aliquot TCGA-A5-A2K5-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7da89a3-b53b-4efd-8fb8-5c7692c4d989

The open-access MAF lists 9,072 somatic variants for this specimen: 7,223 protein-altering or splice-affecting, 1,615 silent, 234 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,087, Silent 1,615, Nonsense Mutation 938, Splice Site 127, Intron 99, RNA 79, Splice Region 35, Frame Shift Ins 21, 3'UTR 19, 5'Flank 15, 3'Flank 11, 5'UTR 11.

Variants (750 of 9,072; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6445C>T p.R2149* | Nonsense Mutation (SNP) | VAF 33/65 reads (51%) | catalogued as rs61750654, CM990078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.2828C>A p.S943* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs1554084512, CM021064, CM086470, COSV57334177, COSV57340756, COSV57390748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as rs886041324, CM041256, CM146776, COSV65812812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs886039673, CM1513964, COSV65808554; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHM | c.1019C>A p.S340* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs1057517714, CM980358, COSV63301242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DLD | c.875+1G>A p.X292_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as rs1328820332, CS034694; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EDA | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs132630312, CM980583, COSV65772037; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as rs137852421, CM0910944, CM920256, COSV64271718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FH | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as rs1131691243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRF6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121434226, CM044898, HM040054, COSV65419014, COSV65419483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF11 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs1554859344; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF5C | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777570, CM1211502; ClinVar: pathogenic; called by muse, varscan2
- MLH1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63751194, CM011411, CM064120, CS105415, COSV51615553, COSV51616044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as rs63750396, CM040458; ClinVar: pathogenic; called by mutect2, varscan2
- MTHFR | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs574132670, CM155651, COSV64701534, COSV64701602; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, varscan2
- NIPBL | c.6796G>T p.E2266* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as rs1554032954; ClinVar: pathogenic; called by mutect2, varscan2
- OAT | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs121965058, CM920531; ClinVar: pathogenic; called by muse, varscan2
- OCRL | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853263, CM050304, COSV63980555; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OLFML2B | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs756430892; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PNPLA1 | c.514G>A p.D172N (on ENST00000394571 / NM_001374623.1; = p.D77N on NM_173676.2) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373148099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PSMD12 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs895130488, COSV62066198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PSTPIP1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs121908130, CM020748, COSV51198632; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs794726799, CM067015, COSV57667265; ClinVar: pathogenic; called by muse, varscan2
- SLC52A3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs267606683, CM101471, CM106571, COSV54079438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774651252, COSV56683792; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCD1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 37/85 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57317934, COSV57318902; called by muse, mutect2, varscan2
- SPATA7 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs140287375, CM113103, COSV50417544; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs751517725, COSV60036110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRAPPC11 | c.3193C>T p.R1065* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as rs750976634, COSV58215661; ClinVar: pathogenic; called by muse, varscan2
- UQCRFS1 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 49/98 reads (50%) | catalogued as rs1242465339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as rs886041382, CM1211563, COSV59875580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.605-1G>T p.X202_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV50970170; called by muse, mutect2, varscan2
- A2M | c.1933C>A p.R645S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV59388094; called by muse, mutect2, varscan2
- A2M | c.1712G>A p.S571N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs746476250; called by mutect2, varscan2
- A2M | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV59393078; called by muse, mutect2, varscan2
- A2ML1 | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100229616; called by muse, mutect2, varscan2
- A2ML1 | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs1370851573, COSV100228669; called by muse, mutect2, varscan2
- AACS | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as rs763684940, COSV55536701; called by mutect2, varscan2
- AADAC | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233379; called by muse, mutect2, varscan2
- AADACL2 | c.1024C>A p.L342I | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV62930435; called by muse, mutect2, varscan2
- AASDH | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV52709038; called by muse, mutect2, varscan2
- ABCA1 | c.4413G>T p.K1471N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.698); catalogued as COSV66065104; called by muse, mutect2, varscan2
- ABCA10 | c.4314A>C p.E1438D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52221308; called by muse, mutect2, varscan2
- ABCA12 | c.1520G>A p.S507N (on ENST00000272895 / NM_173076.3; = p.S189N on NM_015657.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs776360822; called by muse, mutect2, varscan2
- ABCA12 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs193145048, COSV55951779; called by muse, mutect2, varscan2
- ABCA12 | c.342C>G p.N114K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs765181062; called by muse, varscan2
- ABCA13 | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1334169510; called by muse, mutect2, varscan2
- ABCA13 | c.7590G>T p.K2530N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV71288296, COSV71289777; called by muse, mutect2, varscan2
- ABCA13 | c.9042G>T p.K3014N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as COSV71294858; called by mutect2, varscan2
- ABCA13 | c.11863C>T p.Q3955* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs1448884499; called by muse, mutect2, varscan2
- ABCA4 | c.2431C>A p.R811S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.29); catalogued as CM1414491, COSV64671374, COSV64672440; called by mutect2, varscan2
- ABCA5 | c.4709A>C p.K1570T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1456433274; called by muse, mutect2, varscan2
- ABCA6 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs771243934, COSV52641606, COSV99447676; called by muse, mutect2, varscan2
- ABCA6 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs755397102, COSV52641172, COSV52645536; called by muse, varscan2
- ABCB4 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55937335; called by muse, mutect2, varscan2
- ABCB7 | c.1922C>T p.S641L (on ENST00000373394 / NM_001271696.3; = p.S642L on NM_004299.6) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1002483499, COSV99504453; called by muse, mutect2, varscan2
- ABCC4 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs767394657; called by muse, mutect2, varscan2
- ABCC4 | c.2075C>A p.S692Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.284); catalogued as rs939483455; called by mutect2, varscan2
- ABCC9 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV53972690; called by muse, mutect2, varscan2
- ABCD2 | c.1558C>A p.L520I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58053868; called by muse, mutect2, varscan2
- ABCD3 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100239090; called by muse, mutect2, varscan2
- ABCD3 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV64642479; called by muse, mutect2, varscan2
- ABCG8 | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV99700122; called by muse, mutect2, varscan2
- ABHD18 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868003753; called by muse, mutect2, varscan2
- ABL2 | c.1508G>A p.R503Q (on ENST00000502732 / NM_007314.4; = p.R488Q on NM_005158.5) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178157504, COSV61018314; called by muse, mutect2, varscan2
- ABLIM3 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1270449365; called by muse, mutect2, varscan2
- ABT1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1554144825, COSV99223057; called by muse, mutect2, varscan2
- AC008397.2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV62747714; called by muse, mutect2, varscan2
- AC090517.4 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.958); catalogued as rs755149652; called by muse, mutect2, varscan2
- AC092718.8 | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.317); catalogued as COSV59602342; called by muse, mutect2, varscan2
- AC244197.3 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs373820890, CD118228; called by muse, mutect2, varscan2
- ACACB | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as rs969688290; called by muse, mutect2, varscan2
- ACACB | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.895); catalogued as rs778737669; called by mutect2, varscan2
- ACAD11 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.481); catalogued as rs1347523848, COSV53895502; called by muse, mutect2, varscan2
- ACAD11 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as rs1256200245, COSV99392559; called by muse, mutect2, varscan2
- ACAD9 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs748758547, COSV58306406; called by muse, mutect2, varscan2
- ACBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278923333, COSV64729525; called by muse, varscan2
- ACE | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571910640; called by muse, mutect2, varscan2
- ACE2 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.451); catalogued as COSV53023833, COSV53024244; called by muse, mutect2, varscan2
- ACMSD | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1481970814; called by muse, mutect2, varscan2
- ACOT1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs753448518, COSV58574333; called by muse, mutect2, varscan2
- ACOT4 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs576145111; called by muse, mutect2, varscan2
- ACP2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs761987849; called by muse, mutect2, varscan2
- ACSBG1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs763765195, COSV51905663; called by muse, mutect2, varscan2
- ACSBG2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as rs751060741, COSV53123875; called by muse, varscan2
- ACSL3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1177812495, COSV62483596, COSV62485156; called by muse, mutect2, varscan2
- ACSL4 | c.358C>A p.L120I (on ENST00000340800 / NM_022977.2; = p.L79I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV61614846; called by muse, mutect2, varscan2
- ACTA2 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); catalogued as CM104905, COSV56518033; called by muse, mutect2, varscan2
- ACTL9 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV61005539; called by muse, mutect2, varscan2
- ACTN3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1201348087, COSV101557848; called by muse, mutect2, varscan2
- ACTRT1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100947485, COSV100947702; called by muse, mutect2, varscan2
- ACY3 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1439234218; called by muse, mutect2, varscan2
- ADAD2 | c.524C>T p.A175V (on ENST00000315906 / NM_001145400.2; = p.A247V on NM_139174.4) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1470162944; called by mutect2, varscan2
- ADAM10 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as rs770957775; called by muse, varscan2
- ADAM17 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs530963981, COSV60398150; called by muse, mutect2, varscan2
- ADAM19 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV57427667; called by muse, mutect2, varscan2
- ADAM22 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs545692266, COSV55985955; called by muse, mutect2, varscan2
- ADAM22 | c.992+1G>A p.X331_splice | Splice Site (SNP) | VAF 20/94 reads (21%) | catalogued as rs777318270, COSV55973293; called by muse, mutect2, varscan2
- ADAM23 | c.901T>G p.L301V | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs1359041112; called by muse, varscan2
- ADAM23 | c.1747A>G p.N583D | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs756677206; called by muse, mutect2, varscan2
- ADAM29 | c.1073A>C p.E358A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV63661639; called by mutect2, varscan2
- ADAM29 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100821916; called by muse, varscan2
- ADAM29 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63661589; called by muse, varscan2
- ADAM30 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs778961237, COSV65560786; called by muse, mutect2, varscan2
- ADAM8 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs997539004; called by muse, mutect2, varscan2
- ADAMDEC1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs1454716974, COSV56474828; called by muse, mutect2, varscan2
- ADAMTS1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs373846648; called by muse, mutect2, varscan2
- ADAMTS12 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV61254856; called by muse, mutect2, varscan2
- ADAMTS15 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747401091; called by muse, mutect2, varscan2
- ADAMTS16 | c.2070C>A p.F690L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57010551; called by muse, mutect2, varscan2
- ADAMTS18 | c.3284G>T p.R1095I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51412278, COSV51422246; called by muse, mutect2, varscan2
- ADAMTS19 | c.2128A>C p.T710P | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV50747816; called by muse, mutect2
- ADAMTS19 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs145234388, COSV50736858; called by mutect2, varscan2
- ADAMTS2 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.659); catalogued as rs764687535, COSV52386206, COSV52399544; called by muse, mutect2, varscan2
- ADAMTS2 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51081414; called by muse, mutect2, varscan2
- ADAMTS20 | c.5149G>A p.E1717K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67138046; called by muse, mutect2, varscan2
- ADAMTS3 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1178789912; called by muse, varscan2
- ADAMTS3 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV54385585; called by muse, mutect2, varscan2
- ADAMTS6 | c.3233C>A p.S1078Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV58685792; called by muse, mutect2, varscan2
- ADAMTSL1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756246381, COSV52809345; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5258C>A p.S1753Y | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV101000869; called by muse, mutect2, varscan2
- ADARB2 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as rs757814695, COSV67220494; called by mutect2, varscan2
- ADCY10 | c.4351C>T p.P1451S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs773781146; called by muse, mutect2, varscan2
- ADCY10 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as rs764401962, COSV100896905; called by muse, mutect2, varscan2
- ADCY2 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57866908; called by muse, mutect2, varscan2
- ADCY8 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.662); catalogued as rs906181327; called by muse, mutect2, varscan2
- ADGRB1 | c.3240G>T p.M1080I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV60101335; called by muse, mutect2, varscan2
- ADGRB3 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV65384210; called by muse, mutect2, varscan2
- ADGRE1 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0.038); catalogued as COSV99165476; called by muse, mutect2, varscan2
- ADGRF1 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV100982672, COSV64799978; called by muse, mutect2, varscan2
- ADGRF5 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.417); catalogued as COSV51931662, COSV51940173; called by muse, mutect2, varscan2
- ADGRG2 | c.2474G>A p.R825Q (on ENST00000379869 / NM_001079858.3; = p.R822Q on NM_005756.4) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs373883927; called by muse, mutect2, varscan2
- ADGRG4 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs372360005, COSV54966807, COSV99795884; called by muse, mutect2
- ADGRG4 | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751562884, COSV54950446; called by muse, mutect2, varscan2
- ADGRG4 | c.8582C>T p.P2861L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769358480; called by muse, mutect2, varscan2
- ADGRG4 | c.9090G>T p.K3030N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV54963432, COSV99794228; called by muse, mutect2, varscan2
- ADGRL2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs1487870704, COSV54650244, COSV99587694; called by muse, varscan2
- ADGRL3 | c.1673A>G p.Q558R (on ENST00000506720 / NM_001322402.2; = p.Q490R on NM_015236.6) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as rs747498945, COSV72231717; called by muse, mutect2, varscan2
- ADGRL3 | c.1924G>A p.E642K (on ENST00000506720 / NM_001322402.2; = p.E574K on NM_015236.6) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100800343; called by muse, mutect2, varscan2
- ADGRL4 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV66060841; called by muse, mutect2, varscan2
- ADGRV1 | c.7271G>T p.R2424I | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV67988951; called by muse, mutect2, varscan2
- ADGRV1 | c.9830A>C p.N3277T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV67978914; called by muse, mutect2, varscan2
- ADGRV1 | c.16760C>A p.S5587Y | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101316105; called by muse, mutect2, varscan2
- ADGRV1 | c.17860C>A p.L5954M | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67985041; called by muse, mutect2, varscan2
- ADH1A | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 38/103 reads (37%) | catalogued as COSV99266026; called by muse, mutect2, varscan2
- ADH4 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs557732938, COSV55500215; called by muse, mutect2, varscan2
- ADHFE1 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52556218; called by muse, mutect2, varscan2
- ADPGK | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100295331, COSV61173641; called by muse, mutect2, varscan2
- ADSS2 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV63694640, COSV63695668; called by muse, mutect2, varscan2
- ADTRP | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs367932994; called by muse, mutect2, varscan2
- AFAP1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs749129062, COSV61794643; called by muse, mutect2, varscan2
- AGBL4 | c.1098C>A p.F366L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs778347868; called by muse, mutect2, varscan2
- AGBL5 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1361334439; called by muse, mutect2, varscan2
- AGBL5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.57); catalogued as rs1468261345; called by muse, mutect2
- AGL | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV54051877, COSV54059445; called by muse, mutect2, varscan2
- AGTR2 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64156183; called by muse, mutect2, varscan2
- AGTR2 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.271); catalogued as COSV64156282, COSV64156491; called by muse, mutect2, varscan2
- AHCTF1 | c.3727C>T p.R1243* (on ENST00000366508; = p.R1217* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs763622332, COSV58248284; called by mutect2, varscan2
- AHNAK | c.15230C>T p.S5077L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs753736820, COSV57222000; called by muse, mutect2, varscan2
- AHNAK2 | c.17198T>G p.F5733C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766736413; called by muse, varscan2
- AHNAK2 | c.17146G>A p.E5716K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs373089411; called by muse, varscan2
- AHNAK2 | c.8329T>C p.S2777P | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564635013, COSV100315553; called by muse, mutect2, varscan2
- AIM2 | c.345A>C p.R115S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV100931166; called by muse, mutect2, varscan2
- AK5 | c.1213C>A p.L405I (on ENST00000354567 / NM_174858.3; = p.L379I on NM_012093.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.711); catalogued as COSV100642547; called by muse, varscan2
- AK9 | c.4814A>C p.K1605T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV69850274; called by muse, mutect2, varscan2
- AKAP13 | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs1368997410; called by muse, mutect2, varscan2
- AKAP13 | c.2855G>T p.R952I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV100773693; called by muse, mutect2, varscan2
- AKAP13 | c.3962G>A p.S1321N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779156339; called by muse, mutect2, varscan2
- AKAP3 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV57414683; called by muse, mutect2
- AKAP9 | c.11344C>T p.R3782C (on ENST00000359028; = p.R3758C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs779901993, COSV62338810; called by muse, mutect2, varscan2
- AKNAD1 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV62203514; called by muse, mutect2, varscan2
- AKR1C2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs781814762; called by muse, mutect2, varscan2
- AKR1C3 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs199934766; called by muse, mutect2, varscan2
- AKR1D1 | c.858C>A p.I286= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54337502; called by muse, mutect2, varscan2
- AKT2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs761956794; called by muse, mutect2, varscan2
- AL592490.1 | c.2191C>A p.L731I | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.869); catalogued as COSV69426556; called by muse, mutect2, varscan2
- ALAS2 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.913); catalogued as COSV58189173; called by muse, mutect2, varscan2
- ALAS2 | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV58191635; called by muse, mutect2
- ALAS2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.547); catalogued as rs142713771, COSV58193238; called by muse, mutect2, varscan2
- ALDH1A1 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52791369; called by muse, mutect2, varscan2
- ALDH1L1 | c.2430G>T p.M810I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs1559911565; called by muse, mutect2, varscan2
- ALG1 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99275664; called by muse, mutect2, varscan2
- ALG1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as rs775607100, COSV52157770; called by muse, mutect2, varscan2
- ALG10 | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56793012; called by muse, varscan2
- ALG11 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as rs377356876; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG14 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as rs200774756; called by muse, varscan2
- ALK | c.2684C>A p.S895Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66594947; called by muse, mutect2, varscan2
- ALKBH3 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs762849148; called by muse, mutect2, varscan2
- ALMS1 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs376632767, COSV52504065; called by mutect2, varscan2
- ALPK2 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100864326; called by muse, varscan2
- AMIGO1 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs779480021; called by muse, mutect2, varscan2
- AMPD3 | c.2032G>A p.E678K (on ENST00000396553 / NM_001025389.2; = p.E687K on NM_000480.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67330916; called by muse, mutect2, varscan2
- AMPD3 | c.2188C>T p.R730* (on ENST00000396553 / NM_001025389.2; = p.R739* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs755071594, COSV67330872; called by muse, varscan2
- AMPH | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.729); catalogued as COSV57749605; called by muse, mutect2, varscan2
- ANG | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs146485834; called by mutect2, varscan2
- ANGPT1 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52430815; called by muse, mutect2, varscan2
- ANGPT4 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs1196615786; called by muse, mutect2, varscan2
- ANGPTL3 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs375934830; called by muse, mutect2, varscan2
- ANGPTL5 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57532630; called by muse, mutect2
- ANK1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs1563456881; called by muse, mutect2, varscan2
- ANK2 | c.5471C>A p.S1824Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV100000943; called by muse, mutect2, varscan2
- ANK2 | c.5971C>T p.R1991W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442984107, COSV52148543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV55073307; called by muse, mutect2
- ANKRD11 | c.7473C>T p.I2491= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as rs371943158; called by muse, mutect2, varscan2
- ANKRD11 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs779328307, COSV56363342; called by mutect2, varscan2
- ANKRD12 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747490242; called by muse, mutect2, varscan2
- ANKRD12 | c.1770C>A p.F590L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs199694208, COSV100041716; called by muse, mutect2, varscan2
- ANKRD12 | c.2100T>G p.F700L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100041093; called by muse, varscan2
- ANKRD13C | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99257304; called by muse, mutect2, varscan2
- ANKRD16 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 27/48 reads (56%) | catalogued as COSV51948127; called by muse, mutect2, varscan2
- ANKRD17 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV58223986; called by muse, mutect2, varscan2
- ANKRD24 | c.1398G>T p.E466D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53671982; called by mutect2, varscan2
- ANKRD26 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV65775303; called by muse, mutect2, varscan2
- ANKRD26 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs766072180, COSV101066558; called by muse, mutect2, varscan2
- ANKRD27 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs769727812, COSV100042643, COSV60133705; called by muse, varscan2
- ANKRD30A | c.3022G>T p.E1008* (on ENST00000611781; = p.E952* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1564583067, COSV100654250, COSV64604394; called by muse, mutect2, varscan2
- ANKRD34B | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs567016350; called by muse, mutect2, varscan2
- ANKRD36B | c.2141C>A p.S714Y | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1196206781; called by muse, mutect2, varscan2
- ANKRD45 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60960360; called by muse, mutect2, varscan2
- ANKRD6 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs1234779284, COSV60233455; called by muse, mutect2, varscan2
- ANKS1B | c.3391C>T p.R1131C (on ENST00000547776 / NM_152788.4; = p.R297C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs965673606, COSV59124585; called by muse, varscan2
- ANKS1B | c.2735C>A p.S912* (on ENST00000547776 / NM_152788.4; = p.S138* on NM_020140.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV60357807; called by muse, mutect2, varscan2
- ANO3 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV56792783; called by muse, mutect2, varscan2
- ANO5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs199532484, CM137911, COSV61084245; called by muse, mutect2, varscan2
- ANOS1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs754571346, COSV52921277; called by muse, mutect2, varscan2
- ANP32D | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs777687157, COSV56980408; called by mutect2, varscan2
- ANXA1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99973838; called by muse, mutect2, varscan2
- ANXA4 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161360683; called by muse, mutect2, varscan2
- ANXA8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1234169612; called by muse, mutect2, varscan2
- ANXA9 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV104426075; called by muse, mutect2, varscan2
- AOAH | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150438169, COSV51737665; called by muse, mutect2, varscan2
- AOAH | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV51736413, COSV99332448; called by muse, mutect2, varscan2
- AOC1 | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV62867644; called by muse, mutect2, varscan2
- AOPEP | c.1796G>T p.R599I (on ENST00000375315 / NM_001193329.1; = p.R500I on NM_032823.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs969813227; called by muse, mutect2, varscan2
- AOX1 | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs767970704, COSV65982275; called by muse, mutect2, varscan2
- AOX1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101022134; called by muse, mutect2, varscan2
- AP1S1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs760826610, COSV61760476; called by muse, mutect2, varscan2
- AP3M2 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51530558; called by muse, mutect2, varscan2
- APAF1 | c.946G>T p.E316* (on ENST00000551964 / NM_181861.2; = p.E305* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59661340; called by muse, mutect2, varscan2
- APBA3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs762279560, COSV57462429; called by muse, mutect2, varscan2
- APBB3 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as rs772910636; called by muse, mutect2, varscan2
- APC | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57344895; called by muse, mutect2, varscan2
- APC | c.6725G>T p.S2242I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99968776; called by muse, mutect2, varscan2
- APC | c.7720C>A p.L2574I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs876659753, COSV57384137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.8161C>T p.R2721C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs587782312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100895199; called by muse, mutect2, varscan2
- APH1A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs368536742, COSV52530067; called by muse, varscan2
- APOB | c.8013G>T p.K2671N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV51935745, COSV99264561; called by mutect2, varscan2
- APOBEC3F | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs369091002; called by mutect2, varscan2
- AR | c.1841C>A p.S614Y | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV65956652, COSV65959837; called by muse, mutect2, varscan2
- AR | c.2571C>A p.F857L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as CM000308; called by muse, mutect2, varscan2
- ARAP2 | c.1685G>T p.R562I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58289191; called by muse, mutect2, varscan2
- AREL1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV62668368; called by muse, mutect2, varscan2
- ARFGAP1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs368286012; called by mutect2, varscan2
- ARFGEF1 | c.4493G>A p.R1498Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV51605270; called by muse, mutect2, varscan2
- ARHGAP12 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs555184668; called by mutect2, varscan2
- ARHGAP12 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60962390; called by muse, mutect2, varscan2
- ARHGAP15 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV99713592; called by muse, mutect2
- ARHGAP15 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV54488028, COSV99711194; called by muse, mutect2, varscan2
- ARHGAP19 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.357); catalogued as rs1394594504, COSV57392289, COSV57393531; called by muse, mutect2, varscan2
- ARHGAP19 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV57396032, COSV57396164; called by muse, mutect2, varscan2
- ARHGAP21 | c.3028C>T p.R1010* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV57610891; called by muse, mutect2, varscan2
- ARHGAP26 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as rs368631485; called by mutect2, varscan2
- ARHGAP32 | c.1838C>A p.S613Y (on ENST00000310343 / NM_001378025.1; = p.S264Y on NM_014715.4) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100089135; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ARHGAP4 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557103853, COSV63131553; called by muse, mutect2
- ARHGAP9 | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1457444498; called by mutect2, varscan2
- ARHGEF11 | c.3201G>T p.K1067N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59356700; called by mutect2, varscan2
- ARHGEF12 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1486039186, COSV100754663; called by muse, mutect2, varscan2
- ARHGEF28 | c.1610C>A p.P537H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.518); catalogued as COSV99709384; called by muse, mutect2, varscan2
- ARHGEF4 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs758491276; called by muse, mutect2, varscan2
- ARHGEF6 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1321730823; called by muse, varscan2
- ARID1A | c.5299G>T p.E1767* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV61376778; called by muse, mutect2, varscan2
- ARL15 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV72292464, COSV72292873; called by muse, varscan2
- ARL5A | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.704); catalogued as COSV99706581; called by muse, mutect2, varscan2
- ARMC2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV64550529, COSV64553671; called by muse, mutect2, varscan2
- ARMC4 | c.2651A>G p.E884G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV59460720; called by muse, mutect2, varscan2
- ARMC4 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV99518100; called by muse, varscan2
- ARMCX5 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55767258; called by muse, mutect2, varscan2
- ARMH4 | c.1760G>T p.R587I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50773944; called by muse, mutect2, varscan2
- ARPP21 | c.1380C>G p.S460R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV51803517; called by muse, mutect2, varscan2
- ARSL | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV101140584; called by muse, mutect2, varscan2
- ASB16 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs144140141; called by muse, mutect2, varscan2
- ASB17 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs776064305, COSV52409396; called by muse, varscan2
- ASB4 | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1481582711; called by muse, mutect2, varscan2
- ASB5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751252627, COSV56668485; called by muse, mutect2, varscan2
- ASCC1 | c.434G>A p.R145Q (on ENST00000342444 / NM_001369085.1; = p.R117Q on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs779932786, COSV100403693; called by mutect2, varscan2
- ASPH | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV104429982; called by muse, mutect2, varscan2
- ASPM | c.10269G>T p.K3423N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV104399271; called by muse, mutect2, varscan2
- ASPM | c.7958C>T p.S2653F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.031); catalogued as rs1264194975, COSV54126632; called by muse, mutect2, varscan2
- ASTE1 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV53910706; called by muse, mutect2, varscan2
- ASTN1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752367629, COSV56060646; called by muse, mutect2, varscan2
- ASTN2 | c.2173G>A p.D725N (on ENST00000313400 / NM_001365069.1; = p.D674N on NM_014010.5) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.34); catalogued as rs751426907; called by muse, mutect2, varscan2
- ASTN2 | c.1957C>T p.R653C (on ENST00000313400 / NM_001365069.1; = p.R602C on NM_014010.5) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759200691, COSV57763735, COSV57810099; called by mutect2, varscan2
- ASXL3 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52456783; called by muse, mutect2, varscan2
- ASXL3 | c.2198C>A p.S733Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52479097; called by muse, mutect2, varscan2
- ASXL3 | c.5724G>T p.Q1908H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as rs746172646; called by mutect2, varscan2
- ATAD2B | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.639); catalogued as COSV53197454; called by muse, mutect2, varscan2
- ATAD5 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV100429988, COSV58973272; called by muse, mutect2, varscan2
- ATG2A | c.4931C>T p.S1644L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs190479823, COSV65966654; called by muse, mutect2, varscan2
- ATP10B | c.4112C>A p.S1371Y | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs756036351; called by muse, mutect2, varscan2
- ATP10B | c.3459C>A p.F1153L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV100515316; called by muse, varscan2
- ATP10B | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs1201732831; called by muse, mutect2, varscan2
- ATP10D | c.3664G>T p.D1222Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758828166; called by muse, mutect2, varscan2
- ATP11A | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs376507003; called by muse, mutect2, varscan2
- ATP11B | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60026008; called by muse, mutect2, varscan2
- ATP11C | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.091); catalogued as rs868765474; called by muse, mutect2, varscan2
- ATP11C | c.1586G>T p.R529I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs147128476, COSV100557301, COSV59568659, COSV59576357; called by muse, mutect2, varscan2
- ATP12A | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs775442166; called by muse, mutect2, varscan2
- ATP13A5 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1167129944, COSV100665273, COSV60867694; called by muse, mutect2, varscan2
- ATP13A5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs749785921, COSV60865417, COSV60871728; called by muse, mutect2, varscan2
- ATP1B4 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs374060545; called by muse, varscan2
- ATP2A1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs768242653; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs376408495, COSV54854001, COSV54856588; called by muse, varscan2
- ATP2C1 | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs749921964, COSV100146491, COSV100146781; called by muse, mutect2, varscan2
- ATP4A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760879648; called by muse, mutect2, varscan2
- ATP5ME | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 64/157 reads (41%) | catalogued as COSV55325324; called by muse, mutect2, varscan2
- ATP6AP1 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV62341079; called by mutect2, varscan2
- ATP6V0A4 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs769417807, CM065982, COSV59472874; called by mutect2, varscan2
- ATP7A | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1557232786, COSV58451518; called by muse, mutect2, varscan2
- ATP8A2 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54952623, COSV99680590; called by muse, varscan2
- ATP8A2 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs376458112, COSV54956167; called by muse, mutect2, varscan2
- ATP8A2 | c.2549C>T p.S850L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs768924511; called by muse, mutect2, varscan2
- ATP8B1 | c.1169G>T p.W390L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99376836; called by muse, mutect2, varscan2
- ATP8B2 | c.1407C>A p.F469L (on ENST00000672630; = p.F436L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.403); catalogued as rs771087209; called by muse, mutect2, varscan2
- ATP8B4 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs771488564, COSV52726608; called by muse, mutect2, varscan2
- ATR | c.7088G>A p.R2363Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs142918229, COSV63385448; called by muse, mutect2, varscan2
- ATR | c.3547C>T p.R1183* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | catalogued as COSV99052507; called by muse, mutect2, varscan2
- ATR | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs980426116, COSV63387433; called by muse, mutect2, varscan2
- ATRN | c.2920A>G p.M974V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs769963361; called by mutect2, varscan2
- ATRN | c.3470-1G>T p.X1157_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV53534700; called by muse, mutect2, varscan2
- ATRN | c.3714C>A p.F1238L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53532523; called by muse, mutect2, varscan2
- ATRX | c.6440G>T p.S2147I | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1569523183, COSV100971064; ClinVar: uncertain significance; called by muse, mutect2
- ATRX | c.5411C>T p.A1804V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64871312; called by muse, mutect2, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, mutect2, varscan2
- ATRX | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as rs1557140475, COSV64876292; called by muse, mutect2, varscan2
- ATRX | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64878180; called by muse, mutect2, varscan2
- ATXN2 | c.2509G>T p.E837* (on ENST00000550104; = p.E677* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV66484217; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- ATXN2L | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV57378398; called by muse, mutect2, varscan2
- ATXN3L | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376294771, COSV66075374; called by muse, mutect2, varscan2
- AUH | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774105176, COSV57866965; called by muse, mutect2, varscan2
- AURKA | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as COSV57170736; called by muse, mutect2, varscan2
- AVIL | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs549145073, COSV57680547; called by muse, mutect2, varscan2
- AWAT2 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52143914; called by muse, mutect2, varscan2
- AXDND1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as rs148772825; called by muse, mutect2, varscan2
- AXL | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs778883675, COSV56573369; called by muse, mutect2, varscan2
- AZGP1 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV52799370; called by muse, mutect2, varscan2
- B2M | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 49/64 reads (77%) | catalogued as COSV62562883; called by muse, mutect2, varscan2
- B3GALT2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100813635; called by muse, mutect2, varscan2
- B3GAT1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs759852524, COSV56999301; called by muse, mutect2, varscan2
- BAALC | c.466G>T p.E156* (on ENST00000297574 / NM_001364874.1; = p.E121* on NM_024812.3) | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs766189422, COSV52563547; called by muse, mutect2, varscan2
- BACH2 | c.1635C>A p.F545L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57588636, COSV57607475; called by muse, varscan2
- BAIAP3 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs756410804; called by mutect2, varscan2
- BAP1 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV56232316, COSV56237592; called by muse, mutect2, varscan2
- BARD1 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs202118376; called by muse, mutect2, varscan2
- BARHL2 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs775937644, COSV100966033; called by muse, mutect2, varscan2
- BARX2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs376626609; called by mutect2, varscan2
- BAZ1A | c.3709C>A p.Q1237K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.023); catalogued as rs1355299138; called by muse, mutect2, varscan2
- BAZ1B | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100289720; called by muse, mutect2, varscan2
- BAZ2B | c.1449C>A p.F483L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.437); catalogued as rs1164025773, COSV100600701; called by muse, mutect2, varscan2
- BBS10 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV53881041; called by muse, mutect2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BCAS3 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as rs1321744067, COSV66777239; called by muse, mutect2, varscan2
- BCCIP | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV99532851; called by muse, mutect2, varscan2
- BCHE | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs750277149; called by muse, varscan2
- BCL11A | c.485G>T p.R162I (on ENST00000335712 / NM_001365609.1; = p.R196I on NM_018014.4) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1558614470, COSV59628744; called by muse, mutect2, varscan2
- BCL6B | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1364918355; called by muse, mutect2, varscan2
- BCL7C | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs760033767, COSV99288557; called by muse, mutect2, varscan2
- BCLAF1 | c.2104A>C p.K702Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99219203; called by muse, mutect2, varscan2
- BCLAF3 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61413181; called by muse, mutect2
- BCLAF3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs779752496, COSV61413022; called by muse, mutect2, varscan2
- BCLAF3 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61413873; called by muse, varscan2
- BCOR | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60713743, COSV60721284; called by muse, mutect2, varscan2
- BDNF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs779034534, COSV59233109; called by muse, varscan2
- BDP1 | c.3782A>G p.D1261G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62431102; called by muse, mutect2
- BEND2 | c.1712C>A p.S571Y | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66215548; called by muse, mutect2, varscan2
- BEND5 | c.1053G>T p.K351N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65717254; called by muse, mutect2, varscan2
- BFSP1 | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV64900478; called by muse, mutect2, varscan2
- BFSP2 | c.965A>G p.H322R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.134); catalogued as rs750176371; called by muse, mutect2, varscan2
- BHLHE40 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as rs755372991; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2, varscan2
- BICC1 | c.989C>A p.S330Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1350373354, COSV54061624, COSV54064111; called by muse, mutect2, varscan2
- BIRC6 | c.6317C>T p.S2106L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148607215; called by muse, mutect2, varscan2
- BLZF1 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.429); catalogued as COSV61393325; called by muse, mutect2, varscan2
- BLZF1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs753168847; called by muse, mutect2, varscan2
- BMI1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV64958945; called by muse, mutect2, varscan2
- BMP1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs761152073, COSV104403098; called by muse, mutect2, varscan2
- BMP15 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as CM119145; called by muse, mutect2, varscan2
- BMP15 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53140931; called by muse, mutect2, varscan2
- BMP2K | c.988-1G>T p.X330_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as rs1329692280, COSV58593160; called by muse, mutect2, varscan2
- BMPER | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs745668141, COSV51814198; called by muse, mutect2, varscan2
- BNC1 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV61759157; called by muse, mutect2, varscan2
- BNC2 | c.3065C>T p.S1022F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV66167800; called by muse, mutect2, varscan2
- BNC2 | c.1719T>G p.Y573* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV66146618; called by mutect2, varscan2
- BNC2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1272200214; called by muse, mutect2, varscan2
- BRCA1 | c.737T>C p.L246S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CD111173; called by muse, mutect2, varscan2
- BRCA2 | c.1329G>T p.E443D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as rs73169186, COSV66452910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6874G>T p.E2292* | Nonsense Mutation (SNP) | VAF 36/76 reads (47%) | catalogued as COSV104430647; called by muse, mutect2, varscan2
- BRCA2 | c.9995C>A p.S3332Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs876658246, COSV66337711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs200522998, COSV57701317; called by muse, mutect2, varscan2
- BRD9 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs751331882; called by muse, mutect2, varscan2
- BRDT | c.2671G>T p.E891* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV62863294; called by muse, mutect2, varscan2
- BRINP3 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV66518014, COSV66518629; called by muse, mutect2, varscan2
- BRIP1 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs375082407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BROX | c.1151C>A p.T384N | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV61798826; called by muse, mutect2, varscan2
- BRS3 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65711203; called by muse, mutect2, varscan2
- BRWD1 | c.5889dup p.P1964Tfs*10 | Frame Shift Ins (INS) | VAF 17/52 reads (33%) | catalogued as rs1432276975; called by mutect2, pindel, varscan2
- BRWD3 | c.4622C>A p.S1541* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV64744601; called by muse, varscan2
- BRWD3 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100955534, COSV64745044; called by muse, mutect2, varscan2
- BTBD11 | c.2055G>T p.E685D (on ENST00000280758 / NM_001018072.2; = p.E222D on NM_001017523.2) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as COSV55018662; called by muse, mutect2, varscan2
- BTBD3 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV54780708; called by muse, mutect2, varscan2
- BTBD3 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs768807931; called by muse, mutect2, varscan2
- BTK | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as rs782559289, COSV58123217; called by muse, mutect2, varscan2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BVES | c.817-1G>T p.X273_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as COSV58948402; called by muse, mutect2, varscan2
- C10orf71 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60507934; called by muse, mutect2, varscan2
- C10orf71 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV60513302; called by muse, mutect2, varscan2
- C10orf71 | c.1983G>T p.E661D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV60514134; called by muse, mutect2, varscan2
- C11orf98 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); catalogued as rs148572859, COSV63473062; called by mutect2, varscan2
- C12orf50 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs747986135; called by muse, mutect2, varscan2
- C1orf112 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199972566; called by muse, mutect2, varscan2
- C1orf112 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs767191234, COSV53678219; called by muse, mutect2, varscan2
- C1orf56 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1451759697; called by muse, mutect2, varscan2
- C21orf91 | c.770C>A p.S257Y (on ENST00000284881 / NM_001100420.2; = p.S256Y on NM_017447.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370784680; called by mutect2, varscan2
- C2CD3 | c.4323C>A p.F1441L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58093006; called by muse, varscan2
- C2CD3 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs143645446; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2CD5 | c.349+1G>A p.X117_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as COSV61727827; called by muse, mutect2, varscan2
- C2CD6 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV53799937; called by muse, mutect2, varscan2
- C2orf16 | c.5179C>T p.R1727C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as rs745938050, COSV100820671, COSV62676703; called by muse, mutect2, varscan2
- C2orf42 | c.1205G>T p.R402I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1255769776; called by muse, mutect2, varscan2
- C2orf73 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100471498; called by muse, mutect2, varscan2
- C3orf20 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs765984059, COSV53783252; called by muse, mutect2, varscan2
- C4BPA | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV65535804; called by muse, mutect2, varscan2
- C4BPA | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as rs1215951903, COSV65535588; called by muse, varscan2
- C4BPA | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs201262669, COSV65536391; called by muse, varscan2
- C4orf17 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs927190767; called by muse, mutect2, varscan2
- C4orf45 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770056487; called by muse, mutect2, varscan2
- C6orf118 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV104368976; called by mutect2, varscan2
- C6orf47 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV100788960; called by muse, mutect2, varscan2
- C6orf58 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61666874; called by muse, mutect2, varscan2
- C7 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs375964034; called by muse, mutect2, varscan2
- C8orf74 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs1316062752; called by muse, mutect2, varscan2
- C8orf76 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99415086; called by muse, mutect2, varscan2
- C9 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.174); catalogued as COSV99661814; called by muse, varscan2
- C9 | c.584G>T p.R195I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV54675975; called by muse, varscan2
- C9orf72 | c.1259+1G>A p.X420_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as rs776218894; called by muse, mutect2, varscan2
- CA6 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs749482487, COSV66261514; called by muse, mutect2, varscan2
- CA8 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as rs749446493, COSV58771282; called by muse, mutect2, varscan2
- CAB39 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1366529396; called by muse, mutect2, varscan2
- CAB39L | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.173); catalogued as rs1289203124; called by muse, mutect2, varscan2
- CABCOCO1 | c.356T>G p.F119C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs780830270; called by mutect2, varscan2
- CACFD1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as rs782205792, COSV52468775; called by muse, mutect2, varscan2
- CACNA1B | c.5187C>A p.F1729L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV53127039; called by muse, mutect2, varscan2
- CACNA1B | c.6365C>T p.S2122L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.736); catalogued as rs536518993, COSV53134597; called by muse, mutect2, varscan2
- CACNA1C | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs755167125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.2797C>A p.L933M | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100213944, COSV100217381; called by muse, varscan2
- CACNA1C | c.2807T>C p.F936S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs762624889; called by muse, varscan2
- CACNA1D | c.4720C>T p.R1574W (on ENST00000350061 / NM_001128840.3; = p.R1594W on NM_000720.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55442346; called by muse, mutect2, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CACNA1S | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs370861322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as rs1555184488; called by muse, mutect2, varscan2
- CAD | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs779903352, COSV99255001, COSV99255345; called by muse, mutect2, varscan2
- CADM1 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs180710897; called by muse, mutect2, varscan2
- CADM2 | c.701C>T p.S234L (on ENST00000407528 / NM_001167674.2; = p.S236L on NM_153184.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1002347395; called by muse, mutect2, varscan2
- CADM2 | c.883C>T p.R295* (on ENST00000407528 / NM_001167674.2; = p.R297* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs781077819, COSV67361182; called by mutect2, varscan2
- CADPS | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs768666285, COSV51873631; called by muse, mutect2, varscan2
- CADPS2 | c.3569G>A p.R1190Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1292221184, COSV57361913, COSV57385338; called by muse, mutect2, varscan2
- CALB1 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV55367099; called by muse, mutect2, varscan2
- CALCR | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV64007902; called by muse, mutect2, varscan2
- CAMTA2 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.878); catalogued as rs777499606; called by mutect2, varscan2
- CAND2 | c.1094C>T p.S365L (on ENST00000456430 / NM_001162499.2; = p.S272L on NM_012298.3) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs61737053; called by muse, mutect2, varscan2
- CAP2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.053); catalogued as rs755371607; called by mutect2, varscan2
- CAPN2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs755706736, COSV54337754; called by muse, mutect2, varscan2
- CAPN3 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.263); catalogued as rs200759807; ClinVar: uncertain significance; called by mutect2, varscan2
- CAPN3 | c.2218G>A p.G740S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs398123145, COSV99783306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPZA3 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV56851461; called by muse, mutect2, varscan2
- CARD11 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101210606; called by muse, mutect2, varscan2
- CARD6 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as rs756761924; called by muse, mutect2, varscan2
- CARD6 | c.2495G>T p.R832I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV54567052; called by muse, mutect2, varscan2
- CARMIL2 | c.3189C>A p.F1063L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54666393; called by muse, mutect2, varscan2
- CARMIL3 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs772051618; called by muse, varscan2
- CASP14 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs775612358, COSV55666308; called by muse, mutect2, varscan2
- CASP2 | c.114A>C p.E38D | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV60081740; called by muse, mutect2, varscan2
- CASP8AP2 | c.5183C>A p.S1728Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs377357235; called by muse, mutect2, varscan2
- CASP9 | c.1236C>A p.F412L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV61601188, COSV61602073; called by muse, mutect2, varscan2
- CATSPER3 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.841); catalogued as COSV50945401; called by muse, mutect2, varscan2
- CAV2 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs1355914850, COSV99760881; called by muse, mutect2, varscan2
- CBLB | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs201419253; called by muse, mutect2
- CBLL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV60369891, COSV60370312; called by muse, varscan2
- CBLN2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767630045; called by muse, mutect2, varscan2
- CBLN4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50352129, COSV50354495; called by muse, mutect2, varscan2
- CCDC102B | c.1254A>C p.E418D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as COSV60140431; called by mutect2, varscan2
- CCDC120 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1227437292; called by muse, mutect2, varscan2
- CCDC144A | c.2714A>C p.N905T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV100138411; called by mutect2, varscan2
- CCDC149 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371760511; called by muse, mutect2, varscan2
- CCDC150 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs781642729, COSV55871577; called by muse, mutect2, varscan2
- CCDC158 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs752261127, COSV66356281; called by mutect2, varscan2
- CCDC171 | c.1077-1G>T p.X359_splice | Splice Site (SNP) | VAF 22/40 reads (55%) | catalogued as rs766740699, COSV99900550; called by muse, mutect2, varscan2
- CCDC178 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs749760659; called by muse, mutect2, varscan2
- CCDC18 | c.3103C>T p.R1035C (on ENST00000343253 / NM_001306076.1; = p.R1036C on NM_206886.4) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757538758, COSV100159768; called by muse, mutect2, varscan2
- CCDC181 | c.1388G>A p.R463Q (on ENST00000367806 / NM_001300969.1; = p.R462Q on NM_021179.2) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV61394160; called by muse, mutect2, varscan2
- CCDC191 | c.2495T>G p.F832C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1309349979, COSV55676397; called by muse, mutect2
- CCDC22 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1557114239; called by muse, mutect2, varscan2
- CCDC34 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 25/87 reads (29%) | catalogued as rs776561161, COSV58726750; called by muse, mutect2, varscan2
- CCDC39 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as CM131301, COSV56478601; called by muse, varscan2
- CCDC40 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs199948075; called by muse, mutect2, varscan2
- CCDC62 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53430673; called by muse, mutect2, varscan2
- CCDC62 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104386917; called by muse, mutect2, varscan2
- CCDC63 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1327362741; called by muse, mutect2, varscan2
- CCDC63 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs375546177, COSV57530082; called by muse, mutect2, varscan2
- CCDC63 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100370170; called by muse, mutect2, varscan2
- CCDC66 | c.776C>T p.S259L (on ENST00000394672 / NM_001353147.1; = p.S225L on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767018761, COSV58303566; called by mutect2, varscan2
- CCDC68 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV61603141; called by muse, mutect2, varscan2
- CCDC7 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99511577; called by muse, mutect2, varscan2
- CCDC73 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 12/13 reads (92%) | catalogued as COSV58795993; called by muse, varscan2
- CCDC83 | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs762973972, COSV104381831; called by muse, mutect2, varscan2
- CCDC87 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV59580746; called by muse, mutect2, varscan2
- CCDC87 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs199906600, COSV59578459; called by muse, mutect2, varscan2
- CCDC88A | c.5365C>A p.L1789M (on ENST00000436346 / NM_001365480.1; = p.L1761M on NM_018084.5) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV55066589; called by muse, mutect2, varscan2
- CCDC88A | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV55061520; called by muse, mutect2, varscan2
- CCDC88B | c.2638C>T p.R880W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs779565460, COSV57266442; called by muse, mutect2, varscan2
- CCER1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs904714602, COSV62648830; called by muse, mutect2, varscan2
- CCNB1IP1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs376353965; called by muse, mutect2, varscan2
- CCNB3 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147272111, COSV52070070; called by muse, mutect2, varscan2
- CCNG1 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57084420; called by mutect2, varscan2
- CCR5 | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV52751972; called by muse, mutect2, varscan2
- CCT3 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs887651981; called by muse, mutect2, varscan2
- CCT4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780849011, COSV101075188; called by muse, mutect2, varscan2
- CD163 | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as rs768204023; called by muse, mutect2, varscan2
- CD163L1 | c.1410T>C p.D470= | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as COSV58017178; called by muse, mutect2, varscan2
- CD22 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV104373510; called by muse, mutect2, varscan2
- CD2AP | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100830653; called by muse, mutect2, varscan2
- CD5L | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.387); catalogued as rs749437803, COSV100941234; called by muse, varscan2
- CDAN1 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs368759902; called by muse, mutect2, varscan2
- CDC20B | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs376208327; called by muse, mutect2, varscan2
- CDC20B | c.1216-1G>A p.X406_splice | Splice Site (SNP) | VAF 28/50 reads (56%) | catalogued as COSV57052618; called by muse, mutect2, varscan2
- CDC42BPB | c.2406G>T p.Q802H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as rs1335667114; called by muse, mutect2, varscan2
- CDC42BPG | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749631755, COSV61346273; called by mutect2, varscan2
- CDC42EP1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs772130894, COSV50756473; called by muse, mutect2, varscan2
- CDC6 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99266669; called by muse, mutect2, varscan2
- CDC73 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1225502334, COSV66466513; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CDCA2 | c.2821A>G p.T941A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs1298526499, COSV57944416; called by muse, mutect2, varscan2
- CDH10 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1339884733, COSV52571163; called by muse, mutect2, varscan2
- CDH10 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs140810299; called by muse, mutect2, varscan2
- CDH12 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV101201876; called by muse, mutect2, varscan2
- CDH12 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101202754, COSV104428502; called by mutect2, varscan2
- CDH16 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1174435508; called by muse, mutect2, varscan2
- CDH16 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs201022207, COSV100233617; called by muse, mutect2, varscan2
- CDH19 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV50982885; called by muse, varscan2
- CDH2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs753588105, COSV52284130; called by muse, mutect2, varscan2
- CDH22 | c.1644C>A p.F548L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV64837038; called by muse, mutect2, varscan2
- CDH23 | c.4103C>T p.T1368M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762247872, CM127229; ClinVar: uncertain significance; called by muse, varscan2
- CDH26 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54842958; called by muse, mutect2, varscan2
- CDH7 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); catalogued as rs548755121, COSV59881315, COSV59885942; called by muse, mutect2, varscan2
- CDHR3 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1182150723; called by muse, mutect2, varscan2
- CDK19 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349823433, COSV60449149; called by muse, varscan2
- CDK5RAP2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs775616637; called by muse, mutect2, varscan2
- CDKL3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776418302, COSV99527540; called by muse, mutect2, varscan2
- CDKL5 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM136065; called by muse, mutect2, varscan2
- CDKL5 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.225); catalogued as rs772194937, COSV66110224; called by muse, mutect2, varscan2
- CDON | c.3729G>T p.E1243D (on ENST00000392693 / NM_001243597.2; = p.E1220D on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99702079; called by muse, mutect2, varscan2
- CDON | c.3344G>T p.R1115L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs762571384; called by muse, mutect2, varscan2
- CDON | c.2375A>C p.K792T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99700509; called by muse, mutect2
- CDS1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99880356; called by muse, mutect2, varscan2
- CDS2 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs146586086; called by muse, mutect2, varscan2
- CEACAM20 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as COSV57603041; called by muse, mutect2
- CEACAM5 | c.1877C>A p.S626Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99704191; called by muse, mutect2, varscan2
- CEACAM8 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.719); catalogued as COSV54991902; called by muse, mutect2
- CEACAM8 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs371559320; called by mutect2, varscan2
- CEBPZ | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs566727785; called by muse, mutect2, varscan2
- CELF4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs756422800, COSV58454334; called by muse, mutect2, varscan2
- CELSR1 | c.6263G>A p.R2088Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302772854; called by muse, varscan2
- CELSR3 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376559910; called by muse, mutect2, varscan2
- CEMIP2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.223); catalogued as rs548434215, COSV65484674; called by mutect2, varscan2
- CENPC | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752714819, COSV56621438; called by muse, mutect2, varscan2
- CENPC | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99893997; called by muse, mutect2, varscan2
- CENPC | c.514A>C p.N172H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56622908; called by muse, mutect2, varscan2
- CENPE | c.6488C>T p.S2163F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs759827260; called by muse, mutect2, varscan2
- CENPF | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1305998025, COSV65276794; called by muse, mutect2, varscan2
- CENPF | c.4227G>T p.E1409D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV65273638; called by muse, mutect2, varscan2
- CENPF | c.5879G>T p.R1960I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65278747; called by muse, mutect2, varscan2
- CENPF | c.8533G>T p.E2845* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV65273276; called by muse, mutect2, varscan2
- CENPL | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100616349; called by muse, mutect2, varscan2
- CENPN | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs745658924, COSV55141960; called by muse, mutect2, varscan2
- CENPS | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV58363868; called by muse, mutect2, varscan2
- CEP126 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs745899466; called by muse, varscan2
- CEP128 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs750455682, COSV53674001; called by muse, mutect2, varscan2
- CEP162 | c.2716C>T p.R906W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as rs765855388; called by muse, mutect2, varscan2
- CEP290 | c.4139C>A p.S1380Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100468662; called by muse, mutect2, varscan2
- CEP350 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs376245955; called by muse, mutect2, varscan2
- CEP83 | c.1715C>A p.S572Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV104410886; called by muse, mutect2
- CEP97 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs767173679, COSV59123277; called by mutect2, varscan2
- CERCAM | c.1311G>T p.E437D | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.158); catalogued as rs1414572839, COSV65710841; called by muse, varscan2
- CERKL | c.1028G>A p.R343H (on ENST00000339098 / NM_001030311.2; = p.R317H on NM_201548.5) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs150587104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERKL | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV59213217; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as rs1217385253, COSV99267448; called by muse, mutect2, varscan2
- CFAP45 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV63648087; called by muse, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP47 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759375823; called by muse, mutect2, varscan2
- CFAP47 | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV52888593; called by muse, mutect2
- CFAP47 | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as COSV52883816, COSV52888611; called by muse, mutect2, varscan2
- CFAP47 | c.5051C>A p.S1684Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV57975716; called by muse, mutect2, varscan2
- CFAP47 | c.5339G>T p.R1780I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57971423; called by muse, mutect2, varscan2
- CFAP52 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs766919743; called by muse, mutect2, varscan2
- CFAP54 | c.8181G>T p.K2727N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.858); catalogued as rs1477030773, COSV61572996; called by muse, mutect2, varscan2
- CFAP58 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV57213800; called by muse, mutect2, varscan2
- CFAP61 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140848360; called by muse, mutect2, varscan2
- CFAP69 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV100290396; called by muse, mutect2, varscan2
- CFAP69 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs773322992, COSV60185360; called by muse, mutect2
- CFAP70 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs144012531; called by muse, mutect2, varscan2
- CFAP74 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as rs746490453, COSV54564801; called by muse, mutect2, varscan2
- CFAP91 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.017); catalogued as rs1010499390, COSV99847201; called by muse, mutect2, varscan2
- CFP | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV55949718; called by muse, mutect2, varscan2
- CFTR | c.1621C>A p.L541I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.608); catalogued as COSV50073317; called by muse, mutect2, varscan2
- CGAS | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.175); catalogued as rs768207867; called by muse, varscan2
- CGNL1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs921849547, COSV99847148; called by muse, mutect2, varscan2
- CHD2 | c.4250G>T p.R1417I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV101245647; called by muse, mutect2, varscan2
- CHD3 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1156449264; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CHD5 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1397903786; called by muse, mutect2, varscan2
- CHD6 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64691689; called by muse, mutect2, varscan2
- CHD8 | c.1999G>T p.E667* (on ENST00000646647 / NM_001170629.2; = p.E388* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | catalogued as rs1555316382, COSV101303254; called by muse, mutect2, varscan2
- CHD9 | c.6479G>A p.R2160Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs570326018; called by muse, mutect2, varscan2
- CHEK1 | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.868); catalogued as rs751719325; called by muse, varscan2
- CHID1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as rs1339909384; called by muse, mutect2, varscan2
- CHL1 | c.1804G>A p.D602N (on ENST00000397491 / NM_001253387.1; = p.D618N on NM_006614.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs186218301; called by muse, mutect2, varscan2
- CHL1 | c.2606G>T p.R869I (on ENST00000397491 / NM_001253387.1; = p.R885I on NM_006614.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1458037430, COSV56593572, COSV56597924; called by muse, mutect2, varscan2
- CHML | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs920323227, COSV59363700; called by muse, mutect2, varscan2
- CHRM2 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57772049; called by muse, mutect2, varscan2
- CHRNA6 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs138339131, COSV52380245; called by muse, varscan2
- CHRNB1 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60141505; called by muse, mutect2, varscan2
- CHST9 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs769029082, COSV52446376; called by muse, mutect2, varscan2
- CKAP2 | c.1594G>T p.E532* (on ENST00000378037 / NM_001098525.2; = p.E531* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs1314196941; called by muse, mutect2, varscan2
- CKAP2 | c.1817dup p.V607Gfs*4 (on ENST00000378037 / NM_001098525.2; = p.V606Gfs*4 on NM_018204.5) | Frame Shift Ins (INS) | VAF 8/17 reads (47%) | catalogued as rs752250702; called by mutect2, varscan2
- CKAP5 | c.2678T>G p.F893C | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56367799; called by muse, varscan2
- CKMT2 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV54174108; called by muse, mutect2, varscan2
- CLASP2 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs1362042788, COSV104407415; called by muse, varscan2
- CLASP2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367913700; called by muse, mutect2, varscan2
- CLCC1 | c.604G>A p.E202K (on ENST00000356970 / NM_001377464.1; = p.E152K on NM_015127.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs767760185, COSV56763326; called by muse, mutect2, varscan2
- CLCN7 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV99247708; called by muse, mutect2, varscan2
- CLDN25 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371445026; called by muse, mutect2, varscan2
- CLDND1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs373607092; called by muse, mutect2, varscan2
- CLEC4F | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV55479480; called by muse, mutect2, varscan2
- CLIC2 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs781997025, COSV58936394; called by muse, mutect2, varscan2
- CLIP3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs749359354; called by mutect2, varscan2
- CLK1 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 36/78 reads (46%) | catalogued as COSV58435039; called by muse, mutect2, varscan2
- CLMP | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.443); catalogued as rs528513453, COSV71649754; called by muse, mutect2, varscan2
- CLRN1 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as COSV55807208; called by muse, mutect2, varscan2
- CLSTN1 | c.1894G>A p.E632K (on ENST00000377298 / NM_001009566.3; = p.E622K on NM_014944.4) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1224013397, COSV63646629; called by muse, mutect2, varscan2
- CLTCL1 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782377086; called by muse, mutect2, varscan2
- CLTCL1 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1555953364, COSV54227228; called by muse, mutect2, varscan2
- CLTRN | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | catalogued as rs1189099507; called by muse, mutect2, varscan2
- CLUL1 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs751595375; called by mutect2, varscan2
- CMAS | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs978646578, COSV57556693; called by muse, varscan2
- CMIP | c.483G>T p.K161N (on ENST00000537098 / NM_198390.2; = p.K67N on NM_030629.3) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.977); catalogued as rs1454676378; called by muse, mutect2, varscan2
- CMIP | c.735C>A p.F245L (on ENST00000537098 / NM_198390.2; = p.F151L on NM_030629.3) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as COSV101220879; called by muse, mutect2, varscan2
- CMTM8 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as rs142284590; called by mutect2, varscan2
- CMYA5 | c.7323T>G p.I2441M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV71405085; called by muse, mutect2, varscan2
- CNBD1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1330613877, COSV72916988; called by muse, mutect2
- CNBD1 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs774426451, COSV73074095; called by muse, mutect2, varscan2
- CNGA1 | c.1226G>T p.R409I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs1281656808, COSV62053963; called by muse, mutect2, varscan2
- CNGA2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs769231187, COSV61704551; called by muse, mutect2, varscan2
- CNGB3 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 59/73 reads (81%) | catalogued as rs1033335003, COSV100181459; called by muse, mutect2, varscan2
- CNGB3 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369526115, COSV60693835; called by muse, mutect2, varscan2
- CNOT4 | c.1569C>A p.F523L (on ENST00000315544 / NM_001190848.1; = p.F520L on NM_013316.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs1331755697, COSV59650175; called by muse, mutect2, varscan2
- CNOT4 | c.1235G>A p.R412Q (on ENST00000315544 / NM_001190848.1; = p.R409Q on NM_013316.4) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.361); catalogued as rs376005439, COSV59657725; called by muse, mutect2, varscan2
- CNR1 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV62991550; called by muse, mutect2, varscan2
- CNTD1 | c.475A>C p.K159Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs779554107; called by muse, mutect2, varscan2
- CNTLN | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs1456302187, COSV52076815, COSV52095991; called by muse, mutect2, varscan2
- CNTN1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1390176620, COSV61636215; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, mutect2, varscan2
- CNTN5 | c.2148G>C p.W716C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381719081; called by muse, mutect2, varscan2
- CNTN5 | c.2707C>A p.L903I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV99674014; called by muse, mutect2, varscan2
- CNTNAP2 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as rs781236853, CM080155; called by muse, mutect2, varscan2
- CNTNAP4 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.043); catalogued as rs868618889; called by muse, mutect2, varscan2
- CNTNAP5 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs547539440, COSV70490843; called by muse, mutect2, varscan2
- CNTNAP5 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV70487388; called by muse, mutect2, varscan2
- CNTNAP5 | c.2872G>A p.G958S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771762487, COSV70479440; called by muse, mutect2, varscan2
- CNTNAP5 | c.3435G>T p.E1145D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV70507737, COSV70511265; called by muse, mutect2, varscan2
- COG1 | c.2764C>T p.R922* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs549011927, COSV55429515; called by mutect2, varscan2
- COL11A1 | c.1558C>A p.L520I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV100617651; called by muse, mutect2, varscan2
- COL11A1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs150144437; called by muse, mutect2, varscan2
- COL12A1 | c.4867G>T p.D1623Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100485913; called by muse, mutect2, varscan2
- COL14A1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs763832906, COSV99920501; called by muse, mutect2, varscan2
- COL14A1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV52848487; called by muse, mutect2
- COL14A1 | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as rs367703565, COSV52855037; called by muse, mutect2, varscan2
- COL16A1 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429079160; called by muse, mutect2, varscan2
- COL1A2 | c.3266C>A p.A1089D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV51964334; called by muse, mutect2
- COL21A1 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV55165939; called by muse, mutect2, varscan2
- COL24A1 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65310971; called by muse, mutect2, varscan2
- COL4A3 | c.3904C>A p.L1302I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as rs905632374; called by muse, varscan2
- COL4A4 | c.4694G>A p.R1565H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200109045; called by muse, varscan2
- COL4A5 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV60364991; called by muse, mutect2, varscan2
- COL4A5 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865842167, COSV60362202; called by muse, varscan2
- COL5A2 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104425978; called by muse, mutect2, varscan2
- COL5A3 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs752279599; called by muse, mutect2, varscan2
- COL6A1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.763); catalogued as rs1309822720, COSV62611406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.117); catalogued as rs777883035; called by muse, mutect2, varscan2
- COL6A1 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748997622, COSV62612294; called by muse, mutect2, varscan2
- COL6A2 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100152809, COSV56004151; called by muse, mutect2, varscan2
- COL6A2 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.203); catalogued as rs373611722; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV62027295; called by muse, mutect2, varscan2
- COL6A6 | c.5812C>T p.R1938W | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as rs767894123; called by muse, mutect2, varscan2
- COP1 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV58162390, COSV58179829; called by muse, mutect2, varscan2
- COPG2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1554440439, COSV56227954; called by muse, mutect2, varscan2
- COQ4 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1480749307; called by muse, mutect2, varscan2
- CORIN | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs765048638, COSV56695037; called by muse, varscan2
- CPA6 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775233588, COSV52721227; called by mutect2, varscan2
- CPAMD8 | c.628-1G>A p.X210_splice (on ENST00000651564; = p.X163_splice on NM_015692.5) | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as COSV99359831; called by muse, mutect2, varscan2
- CPB2 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51673846; called by muse, mutect2, varscan2
- CPE | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV68580072; called by muse, mutect2, varscan2
- CPEB4 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV54171967; called by mutect2, varscan2
- CPLX4 | c.370C>A p.L124I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as COSV55313253; called by muse, mutect2, varscan2
- CPNE3 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs779231067; called by muse, mutect2, varscan2
- CPQ | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs747760951; called by muse, varscan2
- CPS1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553509661, CM1510933, COSV51828095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF1 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs782373256; called by muse, mutect2
- CPVL | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775870649, COSV55301375; called by muse, mutect2, varscan2
- CR1 | c.3458G>T p.R1153I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs754099919; called by mutect2, varscan2
- CRACD | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs758586331, COSV51720199, COSV51733496; called by muse, mutect2, varscan2
- CRACD | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51734317; called by muse, mutect2, varscan2
- CRB1 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV66348659; called by muse, mutect2, varscan2
- CRMP1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs376766526, COSV61478985; called by muse, mutect2, varscan2
- CROT | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs957533383, COSV58975832; called by muse, mutect2, varscan2
- CROT | c.1038T>G p.I346M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.527); catalogued as rs1375013389; called by muse, mutect2, varscan2
- CRTAC1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs759233240, COSV100086357; called by muse, mutect2, varscan2
- CRTC1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1177950459; called by muse, mutect2, varscan2
- CRYBG1 | c.5740C>A p.L1914I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64810448; called by muse, mutect2, varscan2
- CRYBG2 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.926); catalogued as COSV57485885; called by muse, mutect2, varscan2
- CRYGB | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs761343235, COSV53679614; called by mutect2, varscan2
- CRYGS | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as rs772949005, COSV57192242; called by muse, mutect2, varscan2
- CRYZ | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.91); catalogued as rs748253759, COSV61718855; called by muse, mutect2, varscan2
- CSDC2 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.185); catalogued as COSV104369348; called by muse, mutect2, varscan2
- CSDE1 | c.1534C>T p.R512C (on ENST00000358528 / NM_001007553.3; = p.R481C on NM_007158.6) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1379534757, COSV54744086; called by muse, mutect2, varscan2
- CSDE1 | c.989G>A p.R330Q (on ENST00000358528 / NM_001007553.3; = p.R299Q on NM_007158.6) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs777390495, COSV54754094; called by mutect2, varscan2
- CSMD3 | c.9380G>A p.R3127Q (on ENST00000297405 / NM_001363185.1; = p.R2958Q on NM_052900.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.888); catalogued as rs752773200, COSV52165293, COSV52249136; called by muse, mutect2, varscan2
8,322 further variants in this file (6,473 protein-altering or splice-affecting, 1,615 silent, 234 other) are not listed here.
